Somatic mutation profile of tumor specimen MBCProject_0454_T2_WES (aliquot MBCProject_0454_T2_WES_1) from CMI case MBCProject_0454, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct and lobular carcinoma; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 33.5 years (12,228 days).
Specimen MBCProject_0454_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d157bd0-c151-47ab-8f42-a10ef941b61d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0454_SALIVA (Saliva), aliquot MBCProject_0454_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6429f316-10e0-4776-8715-6b819e456b2d

The open-access MAF lists 35 somatic variants for this specimen: 18 protein-altering or splice-affecting, 8 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 8, Intron 6, Splice Site 2, Splice Region 2, 5'UTR 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASTN1 | c.3526G>A p.A1176T | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62491803, COSV62494609; called by muse, mutect2, varscan2
- ATP6V0D2 | c.836A>C p.E279A | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.082); catalogued as COSV53415693; called by muse, mutect2
- INF2 | c.3199G>A p.G1067S | Missense Mutation (SNP) | VAF 40/248 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs1328349434; called by muse, mutect2, varscan2
- PARK7 | c.253-2A>G p.X85_splice | Splice Site (SNP) | VAF 28/396 reads (7%) | catalogued as COSV58579590; called by muse, mutect2
- PCDHA5 | c.955A>G p.I319V | Missense Mutation (SNP) | VAF 13/139 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.093); catalogued as rs782065651; called by muse, mutect2
- PCLO | c.5541A>T p.E1847D | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as COSV61626041; called by muse, mutect2, varscan2
- BFAR | c.101G>T p.C34F | Missense Mutation (SNP) | VAF 46/335 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BOLA3 | c.54+6C>A | Splice Region (SNP) | VAF 92/813 reads (11%) | called by muse, mutect2, varscan2
- CACNA1D | c.3315G>T p.A1105= (on ENST00000350061 / NM_001128840.3; = p.A1125= on NM_000720.4) | Splice Region (SNP) | VAF 28/524 reads (5%) | called by muse, mutect2
- CELF2 | c.423G>T p.K141N (on ENST00000416382 / NM_001025077.3; = p.K148N on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2
- MAP4K1 | c.2003C>T p.S668F | Missense Mutation (SNP) | VAF 89/386 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- PIWIL1 | c.932+1G>C p.X311_splice | Splice Site (SNP) | VAF 12/88 reads (14%) | called by muse, mutect2
- PRR9 | c.220C>A p.L74I | Missense Mutation (SNP) | VAF 45/396 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- SLC15A1 | c.1460G>C p.G487A | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2
- TBC1D9 | c.1632C>A p.D544E | Missense Mutation (SNP) | VAF 37/271 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- UNCX | c.374A>G p.N125S | Missense Mutation (SNP) | VAF 24/266 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.387); called by muse, mutect2
- ZNF761 | c.1100C>T p.S367L | Missense Mutation (SNP) | VAF 33/286 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); called by muse, varscan2
- ZNF761 | c.1184C>T p.S395L | Missense Mutation (SNP) | VAF 34/290 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.499); called by muse, varscan2
- CAMK2B | c.1218C>T p.D406= | Silent (SNP) | VAF 19/138 reads (14%) | catalogued as rs756933665, COSV51662695; called by muse, mutect2, varscan2
- HDAC9 | c.1530G>A p.Q510= | Silent (SNP) | VAF 24/205 reads (12%) | catalogued as rs745581313; called by muse, mutect2, varscan2
- ITPR1 | c.7590G>A p.T2530= (on ENST00000354582; = p.T2475= on NM_002222.7) | Silent (SNP) | VAF 38/339 reads (11%) | catalogued as rs146028585; called by muse, mutect2, varscan2
- LYSMD4 | c.147G>T p.R49= (on ENST00000409796 / NM_001284417.2; = p.G20V on NM_152449.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/362 reads (10%) | called by muse, mutect2, varscan2
- OR7D4 | c.99C>T p.S33= | Silent (SNP) | VAF 14/101 reads (14%) | called by muse, mutect2, varscan2
- SLC17A4 | c.216C>T p.S72= | Silent (SNP) | VAF 56/301 reads (19%) | catalogued as rs1266856407; called by muse, mutect2, varscan2
- SLC22A4 | c.1173A>G p.L391= | Silent (SNP) | VAF 39/345 reads (11%) | called by muse, mutect2, varscan2
- TENM2 | c.7767C>A p.A2589= (on ENST00000518659 / NM_001122679.2; = p.A2350= on NM_001080428.3) | Silent (SNP) | VAF 14/292 reads (5%) | called by muse, mutect2
- ALAS2 | c.-15-1832C>T | Intron (SNP) | VAF 31/193 reads (16%) | called by muse, mutect2, varscan2
- ALAS2 | c.-15-1833G>A | Intron (SNP) | VAF 29/190 reads (15%) | called by muse, mutect2, varscan2
- DAO | chr12:108879824 G>C | 5'Flank (SNP) | VAF 18/222 reads (8%) | catalogued as COSV57322574; called by muse, mutect2
- KCNH2 | c.1945+12C>T | Intron (SNP) | VAF 12/265 reads (5%) | called by muse, mutect2
- NAP1L1 | c.917-28A>C | Intron (SNP) | VAF 11/78 reads (14%) | called by muse, mutect2, varscan2
- ST8SIA5 | c.132-16742C>T | Intron (SNP) | VAF 12/248 reads (5%) | called by muse, mutect2
- TBXT | c.-11C>T | 5'UTR (SNP) | VAF 16/306 reads (5%) | catalogued as rs1198430776; called by muse, mutect2
- TNFAIP2 | c.1423-40C>T | Intron (SNP) | VAF 79/602 reads (13%) | called by muse, mutect2, varscan2
- VRK3 | chr19:49972069 C>T | 3'Flank (SNP) | VAF 10/208 reads (5%) | called by muse, mutect2
